CCDI case PBCFAF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/61d937cf-914c-4949-8d77-782d3e539051

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,809 days).

Biospecimens (2 samples)
- Sample 0DQHAH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQHB0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
